Somatic mutation profile of cancer-model specimen HCM-CSHL-0634-C30-85A (3D Organoid, passage 9; aliquot HCM-CSHL-0634-C30-85A-01D-A88G-36), derived from the primary tumor of HCMI case HCM-CSHL-0634-C30, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Nasal cavity; Tumor grade: G1.
Specimen HCM-CSHL-0634-C30-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb7d9711-8b77-41c7-bf1c-49be188dcec2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0634-C30-10A (Blood Derived Normal), aliquot HCM-CSHL-0634-C30-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/874371f5-48d7-400f-8629-c3635d9c543a

The open-access MAF lists 73 somatic variants for this specimen: 49 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 21, Nonsense Mutation 4, Frame Shift Del 4, Intron 2, Frame Shift Ins 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC7A7 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 88/321 reads (27%) | catalogued as rs386833807, HM080049, COSV53536587; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC099489.1 | c.5083G>A p.V1695I | Missense Mutation (SNP) | VAF 24/367 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs778255733; called by muse, mutect2
- ADAMTS14 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 122/275 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV64601070; called by muse, mutect2, varscan2
- ADCY7 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 181/390 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as rs199712113; called by muse, mutect2, varscan2
- AJAP1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 187/428 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1362035936, COSV65452111; called by muse, mutect2, varscan2
- BRSK1 | c.1540G>A p.G514R | Missense Mutation (SNP) | VAF 214/485 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as rs1399860068, COSV58668443; called by muse, mutect2, varscan2
- CHRNB3 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 384/384 reads (100%) | SIFT tolerated (0.62); PolyPhen benign (0.088); catalogued as rs1285336246, COSV51495078, COSV51495562; called by muse, mutect2, varscan2
- DNAL1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 111/213 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs536740472; called by muse, mutect2, varscan2
- EMC3 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 239/239 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs144158403; called by muse, mutect2, varscan2
- FEZF1 | c.667del p.Q223Rfs*8 | Frame Shift Del (DEL) | VAF 228/311 reads (73%) | catalogued as COSV58659893; called by mutect2, pindel, varscan2
- GOLGA3 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 211/674 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773386388, COSV52629397; called by muse, mutect2, varscan2
- ILDR1 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 138/586 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs201585253, COSV56549723; called by muse, mutect2, varscan2
- KCNT2 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs760487848, COSV99653623; called by muse, mutect2, varscan2
- LAMP3 | c.1244G>A p.R415K | Missense Mutation (SNP) | VAF 140/618 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55615819; called by muse, mutect2, varscan2
- NLGN2 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 329/694 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1158334530; called by muse, mutect2, varscan2
- NLRP13 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 26/568 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV100738204, COSV61624477; called by muse, mutect2
- NTRK3 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 26/410 reads (6%) | catalogued as rs764653626; called by muse, mutect2
- PRTG | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 212/449 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs949807137; called by muse, mutect2, varscan2
- PSME4 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 48/730 reads (7%) | catalogued as COSV66367042; called by muse, mutect2
- PWWP2B | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 438/882 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs779442728; called by muse, mutect2, varscan2
- RMDN2 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 142/309 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs779891138; called by muse, mutect2, varscan2
- RTN3 | c.1144A>G p.S382G (on ENST00000377819 / NM_001265589.2; = p.S363G on NM_201428.3) | Missense Mutation (SNP) | VAF 153/290 reads (53%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs369380035; called by muse, mutect2, varscan2
- SLC32A1 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 37/980 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV54146196; called by muse, mutect2
- SMPDL3B | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746544808; called by muse, mutect2
- TECTA | c.4672G>T p.D1558Y | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs770705318; called by muse, mutect2
- TLCD3B | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 231/514 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs140155911; called by muse, mutect2, varscan2
- XAB2 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 284/565 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs745944962; called by muse, mutect2, varscan2
- ZMYM2 | c.926C>G p.S309* | Nonsense Mutation (SNP) | VAF 185/444 reads (42%) | catalogued as COSV67038052; called by muse, mutect2, varscan2
- AFM | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- C2CD2L | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 264/539 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- C9orf50 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 92/1218 reads (8%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.55); called by muse, mutect2
- CDH20 | c.39G>T p.W13C | Missense Mutation (SNP) | VAF 127/262 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- DYNC2H1 | c.9069G>T p.L3023F | Missense Mutation (SNP) | VAF 121/269 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- EP400 | c.6131A>T p.E2044V | Missense Mutation (SNP) | VAF 248/817 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KDM6A | c.2303dup p.S769Vfs*22 | Frame Shift Ins (INS) | VAF 210/296 reads (71%) | called by mutect2, pindel, varscan2
- KPTN | c.803C>A p.P268Q | Missense Mutation (SNP) | VAF 159/318 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- LAIR1 | c.36G>T p.V12= | Splice Region (SNP) | VAF 233/511 reads (46%) | called by muse, mutect2, varscan2
- LAPTM4A | c.638C>A p.P213Q | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LYPD8 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 132/402 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEL2 | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 367/875 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- NELL2 | c.1751G>C p.R584T | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); called by muse, mutect2
- RIMBP2 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 32/968 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- SLC25A43 | c.611A>C p.N204T | Missense Mutation (SNP) | VAF 305/305 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TP53 | c.385_400del p.A129Ffs*36 | Frame Shift Del (DEL) | VAF 302/325 reads (93%) | called by mutect2, pindel, varscan2
- TPTE2 | c.803G>A p.S268N (on ENST00000400230 / NM_199254.2; = p.S191N on NM_130785.3) | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRMT61B | c.646T>G p.L216V | Missense Mutation (SNP) | VAF 163/360 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XRN1 | c.706_707del p.Q236Tfs*23 | Frame Shift Del (DEL) | VAF 77/352 reads (22%) | called by pindel, varscan2
- ZFYVE27 | c.291_292del p.L98Dfs*21 | Frame Shift Del (DEL) | VAF 142/341 reads (42%) | called by mutect2, pindel, varscan2
- ZNF497 | c.599dup p.R201Pfs*127 | Frame Shift Ins (INS) | VAF 347/831 reads (42%) | called by mutect2, pindel, varscan2
- ATP1A4 | c.1386A>T p.S462= | Silent (SNP) | VAF 145/431 reads (34%) | called by muse, mutect2, varscan2
- C1QTNF12 | c.246G>A p.P82= | Silent (SNP) | VAF 266/538 reads (49%) | catalogued as rs140614324; called by muse, mutect2, varscan2
- CAPN12 | c.1563C>G p.S521= | Silent (SNP) | VAF 153/504 reads (30%) | called by muse, mutect2, varscan2
- CLIP4 | c.331T>C p.L111= | Silent (SNP) | VAF 137/322 reads (43%) | called by muse, mutect2, varscan2
- CR1 | c.4692G>A p.R1564= | Silent (SNP) | VAF 203/419 reads (48%) | catalogued as COSV65459609; called by muse, mutect2, varscan2
- FMO3 | c.300C>A p.L100= | Silent (SNP) | VAF 130/283 reads (46%) | called by muse, mutect2, varscan2
- HDGFL1 | c.729G>A p.P243= | Silent (SNP) | VAF 276/720 reads (38%) | catalogued as rs968484120, COSV100014565; called by muse, mutect2, varscan2
- KRT26 | c.66C>T p.S22= | Silent (SNP) | VAF 25/604 reads (4%) | catalogued as rs1417094028, COSV100053367, COSV56970629; called by muse, mutect2
- MDFI | c.702G>A p.E234= | Silent (SNP) | VAF 256/483 reads (53%) | catalogued as rs1359343957; called by muse, varscan2
- MSH5 | c.1398G>A p.L466= | Silent (SNP) | VAF 163/339 reads (48%) | called by muse, mutect2, varscan2
- MYEOV | c.168G>A p.S56= | Silent (SNP) | VAF 234/455 reads (51%) | catalogued as rs375533191; called by muse, mutect2, varscan2
- NFE2 | c.801C>T p.V267= | Silent (SNP) | VAF 255/565 reads (45%) | catalogued as COSV100380881; called by muse, mutect2, varscan2
- OAS3 | c.1065C>T p.H355= | Silent (SNP) | VAF 155/346 reads (45%) | called by muse, mutect2, varscan2
- PLCL2 | c.1401C>T p.C467= (on ENST00000615277 / NM_001144382.2; = p.C341= on NM_015184.5) | Silent (SNP) | VAF 143/143 reads (100%) | called by muse, mutect2, varscan2
- RGL3 | c.153C>G p.P51= | Silent (SNP) | VAF 16/343 reads (5%) | called by muse, mutect2
- SCIN | c.1650C>A p.G550= (on ENST00000297029 / NM_001112706.3; = p.G303= on NM_033128.3) | Silent (SNP) | VAF 136/138 reads (99%) | called by muse, mutect2, varscan2
- SFRP1 | c.417G>C p.S139= | Silent (SNP) | VAF 46/617 reads (7%) | catalogued as rs558728015, COSV99617706; called by muse, mutect2
- TJP3 | c.2151C>T p.S717= | Silent (SNP) | VAF 376/784 reads (48%) | catalogued as rs1169550201; called by muse, mutect2, varscan2
- TMEM131 | c.1323A>G p.L441= | Silent (SNP) | VAF 146/313 reads (47%) | catalogued as COSV51772886; called by muse, mutect2, varscan2
- USP17L2 | c.1053T>C p.D351= | Silent (SNP) | VAF 215/1028 reads (21%) | called by muse, mutect2, varscan2
- USP17L2 | c.507G>A p.V169= | Silent (SNP) | VAF 404/876 reads (46%) | called by muse, mutect2, varscan2
- DNAH14 | c.3051+15021A>T | Intron (SNP) | VAF 56/299 reads (19%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-1430A>C | Intron (SNP) | VAF 21/349 reads (6%) | called by muse, mutect2
- SKOR1 | chr15:67822019 G>T | 5'Flank (SNP) | VAF 284/565 reads (50%) | called by muse, mutect2, varscan2
